Somatic mutation profile of tumor specimen ALCH-B1O2-TTP1-A (aliquot ALCH-B1O2-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B1O2, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 67.7 years (24,734 days).
Specimen ALCH-B1O2-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77c83367-da16-4757-9dc2-80953f9ba477.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1O2-NB1-A (Blood Derived Normal), aliquot ALCH-B1O2-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6585bf0a-e340-4c5f-8cda-1e2fb4f1d020

The open-access MAF lists 54 somatic variants for this specimen: 34 protein-altering or splice-affecting, 13 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 13, Intron 4, RNA 3, Nonsense Mutation 3, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 19/176 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587780071, CM120848, COSV52677226, COSV52796536, COSV53623808; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALLC | c.195G>T p.R65S | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV52993587, COSV52997182; called by muse, mutect2
- FAM71C | c.229A>T p.S77C | Missense Mutation (SNP) | VAF 16/296 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1289694518; called by muse, mutect2
- LAMA2 | c.4829A>G p.Y1610C | Missense Mutation (SNP) | VAF 12/381 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); catalogued as COSV70350446; called by muse, mutect2
- LCT | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs760712703, COSV51465173; called by muse, mutect2
- LHX8 | c.795C>A p.S265R | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV53955645; called by muse, mutect2
- LRRC30 | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 12/164 reads (7%) | catalogued as rs780254963; called by muse, mutect2
- MUC16 | c.28706G>T p.G9569V | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.737); catalogued as COSV67480828; called by muse, mutect2
- MYH3 | c.769G>T p.G257W | Missense Mutation (SNP) | VAF 10/183 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99878554; called by muse, mutect2
- PCDH11X | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as COSV53487981; called by muse, mutect2
- RAP1GAP2 | c.1632G>T p.S544= | Splice Region (SNP) | VAF 7/91 reads (8%) | catalogued as COSV54584923; called by muse, mutect2
- ACAN | c.5906C>A p.S1969Y | Missense Mutation (SNP) | VAF 15/201 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAMTS12 | c.2257C>A p.L753M | Missense Mutation (SNP) | VAF 41/232 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAMTS12 | c.2256C>A p.Y752* | Nonsense Mutation (SNP) | VAF 39/229 reads (17%) | called by muse, mutect2, varscan2
- AGAP2 | c.740G>T p.G247V | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.429); called by muse, varscan2
- ALLC | c.194G>T p.R65M | Missense Mutation (SNP) | VAF 6/169 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.08); called by muse, mutect2
- ARMC1 | c.700A>G p.N234D | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.162); called by muse, mutect2
- BPIFB4 | c.1754G>A p.G585D | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.29); PolyPhen probably damaging (1); called by muse, mutect2
- ELAPOR1 | c.1587A>C p.K529N | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.015); called by muse, mutect2
- GRM1 | c.2298C>A p.S766R | Missense Mutation (SNP) | VAF 37/481 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- H3C4 | c.320A>T p.D107V | Missense Mutation (SNP) | VAF 18/460 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- H3C4 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 17/461 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.724); called by muse, mutect2
- HCN1 | c.2524T>C p.F842L | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- IGKV1D-43 | c.197C>A p.P66H | Missense Mutation (SNP) | VAF 25/416 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- INTS6L | c.1381A>G p.M461V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, varscan2
- PAK3 | c.1256-1G>T p.X419_splice (on ENST00000262836 / NM_001324328.2; = p.X404_splice on NM_002578.5 and 4 other RefSeq transcripts) | Splice Site (SNP) | VAF 7/70 reads (10%) | called by muse, mutect2
- PHF20 | c.2929C>A p.L977M | Missense Mutation (SNP) | VAF 10/167 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RUNX2 | c.1469A>G p.Q490R (on ENST00000371438; = p.Q468R on NM_001015051.3) | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SCD5 | c.734A>T p.Y245F | Missense Mutation (SNP) | VAF 12/183 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.075); called by muse, mutect2
- SLC20A1 | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2
- SPP1 | c.516G>C p.K172N (on ENST00000395080 / NM_001040058.2; = p.K158N on NM_000582.2) | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); called by muse, mutect2
- TEX13C | c.951G>T p.K317N | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- TEX13C | c.952G>T p.E318* | Nonsense Mutation (SNP) | VAF 9/84 reads (11%) | called by muse, mutect2, varscan2
- TRPM1 | c.1644C>G p.N548K | Missense Mutation (SNP) | VAF 15/361 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.022); called by muse, mutect2
- COL17A1 | c.3939A>T p.T1313= | Silent (SNP) | VAF 9/178 reads (5%) | called by muse, mutect2
- FAM71C | c.228C>G p.T76= | Silent (SNP) | VAF 16/292 reads (5%) | called by muse, mutect2
- FZD10 | c.279G>A p.P93= | Silent (SNP) | VAF 10/131 reads (8%) | called by muse, mutect2
- NSUN3 | c.939C>T p.L313= | Silent (SNP) | VAF 15/121 reads (12%) | catalogued as rs1343006124; called by muse, mutect2, varscan2
- OR4A5 | c.195A>G p.S65= | Silent (SNP) | VAF 9/82 reads (11%) | called by muse, mutect2, varscan2
- OTOG | c.7788G>T p.V2596= | Silent (SNP) | VAF 11/164 reads (7%) | called by muse, mutect2
- PCDHB1 | c.1908C>A p.P636= | Silent (SNP) | VAF 6/117 reads (5%) | called by muse, mutect2
- PLEC | c.8586G>T p.T2862= (on ENST00000322810 / NM_201380.4; = p.T2752= on NM_000445.5) | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV59650482; called by muse, mutect2
- RBPJL | c.567C>A p.I189= | Silent (SNP) | VAF 8/140 reads (6%) | called by muse, mutect2
- RENBP | c.963G>A p.K321= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV64170271; called by muse, mutect2, varscan2
- TIAF1 | c.159G>A p.V53= | Silent (SNP) | VAF 13/142 reads (9%) | called by muse, mutect2, varscan2
- ZFHX4 | c.2160G>T p.S720= | Silent (SNP) | VAF 9/184 reads (5%) | catalogued as COSV50497786; called by muse, mutect2
- ZNF85 | c.60C>T p.C20= | Silent (SNP) | VAF 10/200 reads (5%) | called by muse, mutect2
- DLX1 | c.513+105T>A | Intron (SNP) | VAF 8/120 reads (7%) | catalogued as rs1393314746; called by muse, mutect2
- DPP10 | c.61-147316G>A | Intron (SNP) | VAF 8/101 reads (8%) | catalogued as rs1355508318; called by muse, mutect2
- DPP6 | c.627+20986A>T | Intron (SNP) | VAF 11/144 reads (8%) | called by muse, mutect2
- HIGD1A | c.-23+208G>T | Intron (SNP) | VAF 5/36 reads (14%) | catalogued as rs1293598905; called by muse, mutect2, varscan2
- LINC01460 | n.639G>T | RNA (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- MIR520D | n.31C>T | RNA (SNP) | VAF 5/89 reads (6%) | called by muse, mutect2
- NOC2LP2 | n.1559A>G | RNA (SNP) | VAF 10/214 reads (5%) | called by muse, mutect2
